Somatic mutation profile of tumor specimen TCGA-22-5492-01A (aliquot TCGA-22-5492-01A-01D-1632-08) from TCGA case TCGA-22-5492, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.5 years (26,838 days).
Specimen TCGA-22-5492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba426697-2e85-4863-a662-6ceddceda183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5492-11A (Solid Tissue Normal), aliquot TCGA-22-5492-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67d3db46-934a-44e2-b3df-5f7758eb8aa9

The open-access MAF lists 253 somatic variants for this specimen: 192 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 55, Nonsense Mutation 12, Splice Site 10, Frame Shift Del 5, Intron 2, Splice Region 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.943-1G>T p.X315_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as rs180177298, CS093822, COSV56756188; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1611C>A p.D537E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61684926, COSV61687202; called by muse, mutect2, varscan2
- ACTC1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV51762166; called by muse, mutect2, varscan2
- ADAM29 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63669305; called by muse, mutect2, varscan2
- ADAMTS15 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV54510502; called by muse, mutect2
- ADAMTS18 | c.1741G>T p.G581W | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043434349, COSV51424671; called by muse, mutect2, varscan2
- ADGRA1 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs1288463074, COSV66927946; called by muse, mutect2, varscan2
- AIMP1 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63639741; called by muse, mutect2, varscan2
- AKAP4 | c.1029C>A p.D343E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62075803; called by muse, mutect2, varscan2
- ALB | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55742612, COSV55743627; called by muse, mutect2, varscan2
- ALOX15 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV53401368; called by muse, mutect2
- ALPK2 | c.3815T>C p.V1272A | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64498350; called by muse, mutect2, varscan2
- APBA2 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs142481200; called by muse, mutect2
- APC | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as CM042290, COSV57322749, COSV57390530; called by muse, mutect2, varscan2
- ARFGEF3 | c.4525T>C p.S1509P | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV52473284; called by muse, mutect2, varscan2
- ASB9 | c.427A>T p.R143W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66852525; called by muse, mutect2, varscan2
- ATP11A | c.252+1G>T p.X84_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV52127261; called by muse, mutect2, varscan2
- B3GNT3 | c.23G>C p.R8P | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV59439467; called by muse, mutect2, varscan2
- BOD1L1 | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs895440006, COSV50097395; called by muse, mutect2, varscan2
- BRWD3 | c.693C>G p.N231K | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64754576; called by muse, mutect2, varscan2
- BTN1A1 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV55070232; called by muse, mutect2, varscan2
- C8orf34 | c.1241+2T>A p.X414_splice | Splice Site (SNP) | VAF 25/45 reads (56%) | catalogued as COSV57415468; called by muse, mutect2, varscan2
- CADM3 | c.733C>T p.R245C (on ENST00000368125 / NM_001127173.3; = p.R279C on NM_021189.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1431857861, COSV63685009; called by muse, mutect2, varscan2
- CAMTA1 | c.4316G>T p.W1439L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.754); catalogued as rs1436594099, COSV57933410; called by muse, mutect2, varscan2
- CAMTA1 | c.4317G>C p.W1439C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57933419; called by muse, mutect2, varscan2
- CCNB3 | c.4049C>A p.S1350Y | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.439); catalogued as COSV52081163; called by muse, mutect2, varscan2
- CD5 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs754316247, COSV61719316; called by muse, mutect2, varscan2
- CDH24 | c.1687A>G p.N563D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57464406; called by muse, mutect2, varscan2
- CDH7 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59897145; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 43/109 reads (39%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- CLCN5 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56587381; called by muse, mutect2, varscan2
- CNGA4 | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66007331; called by muse, mutect2, varscan2
- CNKSR2 | c.2521A>T p.K841* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54268950; called by muse, mutect2, varscan2
- CNTNAP4 | c.2616C>A p.N872K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV56705609, COSV56708519; called by muse, mutect2, varscan2
- CNTNAP5 | c.3443G>T p.G1148V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV70518050; called by muse, mutect2
- COL1A2 | c.2486G>T p.G829V | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51963013, COSV51968172; called by muse, mutect2, varscan2
- COL4A4 | c.4160T>C p.M1387T | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61637587; called by muse, mutect2, varscan2
- CR2 | c.1979-1G>C p.X660_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | catalogued as COSV65510256; called by muse, mutect2, varscan2
- CRISPLD1 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV51553932; called by muse, mutect2, varscan2
- CRYGN | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61564516; called by muse, varscan2
- DNAH7 | c.8876C>G p.T2959R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV56791421; called by muse, mutect2, varscan2
- DNMT3A | c.2039A>G p.K680R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53083583; called by muse, mutect2, varscan2
- DPP10 | c.1281G>C p.K427N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV59741775; called by muse, mutect2, varscan2
- DPY19L1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV60584951; called by muse, mutect2, varscan2
- DSG2 | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV55204127; called by muse, varscan2
- DUSP5 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63647829; called by muse, mutect2, varscan2
- DYNC1H1 | c.7702G>A p.V2568I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs765245789, COSV64144193; called by muse, mutect2, varscan2
- ECT2L | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62885350, COSV62887727; called by muse, mutect2, varscan2
- EGFLAM | c.898T>A p.S300T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.19); catalogued as COSV59320834; called by muse, mutect2, varscan2
- EIF4G1 | c.3020A>G p.K1007R (on ENST00000346169 / NM_198241.3; = p.K812R on NM_004953.5) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV59995019; called by muse, mutect2, varscan2
- EPB41L2 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61359763; called by muse, mutect2, varscan2
- EPB41L3 | c.1341G>A p.E447= | Splice Region (SNP) | VAF 11/78 reads (14%) | catalogued as rs11661706, COSV59471494; called by muse, mutect2, varscan2
- F8 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64279843; called by muse, mutect2, varscan2
- FAM135B | c.3373T>A p.Y1125N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52758874; called by muse, mutect2, varscan2
- FAM13A | c.1721G>T p.W574L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52004091, COSV52015190; called by muse, mutect2, varscan2
- FAM47C | c.2332C>A p.L778I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV63723756; called by muse, mutect2, varscan2
- FAT1 | c.5257G>T p.V1753F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71676374; called by muse, mutect2, varscan2
- FBXO43 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71055840; called by muse, mutect2, varscan2
- FGD6 | c.2760G>C p.Q920H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59698079; called by muse, mutect2, varscan2
- FNDC3B | c.2849T>C p.I950T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV61051494; called by muse, mutect2, varscan2
- FUCA2 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.371); catalogued as COSV50021353; called by muse, mutect2
- GABRQ | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV64784337; called by muse, mutect2, varscan2
- GIPC2 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63379832; called by muse, mutect2, varscan2
- GIPC2 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV63379834; called by muse, mutect2, varscan2
- GRID2 | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1340117284, COSV56199386, COSV56207230; called by muse, mutect2
- GRM3 | c.1634C>G p.T545S | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV64481199; called by muse, mutect2, varscan2
- GRM6 | c.1428G>T p.Q476H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV51451144; called by muse, mutect2, varscan2
- H1-4 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56803960; called by muse, mutect2, varscan2
- HDAC8 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV65240383; called by muse, varscan2
- HEPACAM | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53433093; called by muse, mutect2, varscan2
- HGF | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958815; called by muse, mutect2, varscan2
- HHLA2 | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV63320759; called by muse, mutect2, varscan2
- HPSE | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60989164; called by muse, varscan2
- IFT81 | c.1915T>C p.W639R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54367420; called by muse, mutect2, varscan2
- INO80 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV62743488; called by muse, mutect2, varscan2
- IPO11 | c.2843T>C p.L948P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV57584277; called by muse, mutect2, varscan2
- ITGB3 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71385372; called by muse, varscan2
- ITPRID1 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as rs1419705703, COSV60085024; called by muse, mutect2, varscan2
- KIF5A | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV54060187; called by muse, mutect2, varscan2
- LAMA2 | c.3038C>G p.A1013G | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV70357235; called by muse, varscan2
- MACF1 | c.8535G>T p.R2845S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57150163; called by muse, varscan2
- MAGEA4 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV52342613; called by muse, mutect2, varscan2
- MATN2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774646380, COSV54717539; called by muse, mutect2, varscan2
- MBNL3 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV63731887; called by muse, mutect2, varscan2
- MDM2 | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.625); catalogued as COSV50705594; called by muse, mutect2, varscan2
- MED15 | c.1187A>G p.H396R | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV53034641; called by muse, mutect2, varscan2
- MLH3 | c.2102G>C p.S701T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53160071; called by muse, mutect2, varscan2
- MLXIP | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59838525; called by muse, mutect2, varscan2
- MLXIPL | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57671083; called by muse, mutect2, varscan2
- MOGAT2 | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV52221706; called by muse, mutect2, varscan2
- MORF4L2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1308129450, COSV64611568; called by muse, mutect2, varscan2
- MUC5B | c.9298C>A p.P3100T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV71596663; called by muse, mutect2, varscan2
- MUSK | c.1688C>A p.P563H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV51899278; called by muse, varscan2
- MUSK | c.1690A>T p.K564* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV51894427, COSV51899350; called by muse, varscan2
- MYO15A | c.4551G>C p.Q1517H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52768572; called by muse, mutect2, varscan2
- NAA30 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53650019; called by muse, mutect2, varscan2
- NAP1L2 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65173189; called by muse, mutect2, varscan2
- NARS1 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs367852140; called by muse, mutect2, varscan2
- NDUFA10 | c.999+1G>A p.X333_splice | Splice Site (SNP) | VAF 13/43 reads (30%) | catalogued as COSV53157135; called by muse, mutect2, varscan2
- NEIL1 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs776364885, COSV51250722, COSV99145444; called by muse, mutect2, varscan2
- NIPSNAP2 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV59053239; called by muse, mutect2, varscan2
- NLRP3 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CM013247, COSV60232491; called by muse, mutect2, varscan2
- NOTCH1 | c.5351G>T p.R1784L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53042678, COSV53097961; called by muse, mutect2, varscan2
- NUAK1 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV54609606; called by mutect2, varscan2
- NUP133 | c.2686-1G>C p.X896_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV54576192; called by muse, mutect2, varscan2
- OR13D1 | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59514950, COSV59515290; called by muse, mutect2, varscan2
- OR2F1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67332240; called by muse, mutect2, varscan2
- OR51Q1 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV56178816; called by muse, mutect2, varscan2
- OR51Q1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56178825; called by muse, mutect2, varscan2
- OTULIN | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52507597; called by muse, mutect2
- PAOX | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV53375469; called by muse, mutect2, varscan2
- PAPPA2 | c.4402G>T p.D1468Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs371564283, COSV62814657; called by muse, mutect2, varscan2
- PARP6 | c.1624A>G p.M542V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53005644; called by muse, mutect2, varscan2
- PCDH11X | c.2869A>C p.N957H | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV53514104; called by muse, mutect2, varscan2
- PDE4DIP | c.3746A>G p.E1249G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57735408; called by mutect2, varscan2
- PIAS1 | c.596A>C p.Q199P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51039773; called by muse, mutect2, varscan2
- PKD2L1 | c.1880+1G>C p.X627_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58399556; called by muse, mutect2, varscan2
- PLSCR4 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV61609323; called by muse, mutect2, varscan2
- POLQ | c.5499C>G p.D1833E | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV51763672; called by muse, mutect2, varscan2
- POLR1E | c.787C>T p.P263S (on ENST00000377792 / NM_001282766.1; = p.P201S on NM_022490.4) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66773292; called by muse, mutect2, varscan2
- POLR2B | c.3459C>G p.Y1153* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV55277725; called by mutect2, varscan2
- PPEF2 | c.5del p.G2Efs*24 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | catalogued as COSV54421754; called by mutect2, pindel, varscan2
- PRDM11 | c.283G>T p.D95Y (on ENST00000530656 / NM_001359633.1; = p.D61Y on NM_001256695.1) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV55444721; called by muse, mutect2
- PRKG1 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV64815549; called by muse, mutect2, varscan2
- PRMT5 | c.1778G>T p.R593L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV53549052; called by muse, mutect2, varscan2
- PTCHD1 | c.561C>A p.Y187* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as COSV65060224, COSV65063388; called by muse, mutect2, varscan2
- PTGER3 | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.439); catalogued as COSV60699563; called by muse, mutect2
- PTGER3 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60699571; called by muse, mutect2
- PTPN4 | c.2044A>G p.K682E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55310729; called by muse, mutect2, varscan2
- PTPRD | c.547A>C p.I183L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV61989123; called by muse, mutect2, varscan2
- PTPRN | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.066); catalogued as rs373811949; called by muse, mutect2, varscan2
- PTPRU | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60538623; called by muse, mutect2, varscan2
- PWWP2B | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV59454339; called by muse, mutect2, varscan2
- RHOU | c.413A>T p.N138I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64208655, COSV64209325; called by muse, mutect2, varscan2
- ROBO3 | c.1623C>A p.D541E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV67303382; called by muse, mutect2
- RYR3 | c.5364G>T p.E1788D | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as rs760634766, COSV66811642; called by muse, mutect2, varscan2
- SCN10A | c.4751T>G p.L1584R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV71862849; called by muse, mutect2, varscan2
- SERPINA4 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV54072007; called by muse, mutect2, varscan2
- SFTPA1 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64867933; called by muse, mutect2, varscan2
- SGIP1 | c.2471A>G p.Y824C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV52781433; called by muse, mutect2, varscan2
- SIDT1 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53508774; called by muse, mutect2, varscan2
- SLC25A10 | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV58972319; called by muse, mutect2, varscan2
- SLC4A10 | c.1093C>A p.P365T (on ENST00000446997 / NM_001354461.2; = p.P335T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55804322, COSV99762592; called by muse, mutect2, varscan2
- SP100 | c.2331+1G>T p.X777_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV60852653; called by muse, mutect2, varscan2
- SRPRA | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV55009382; called by muse, mutect2, varscan2
- SYCE1 | c.695G>A p.R232H (on ENST00000343131 / NM_001143764.3; = p.R196H on NM_130784.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs150742469, COSV100385704; called by muse, mutect2, varscan2
- SZT2 | c.5504T>G p.I1835S (on ENST00000634258 / NM_001365999.1; = p.I1778S on NM_015284.4) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV65175976; called by muse, mutect2, varscan2
- TAF3 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV60212979; called by muse, mutect2, varscan2
- TBC1D8B | c.1356G>A p.L452= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as COSV52184504; called by mutect2, varscan2
- TDG | c.479-1G>A p.X160_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as rs982930808, COSV57165005, COSV57165590, COSV57169044; called by muse, mutect2, varscan2
- TENM3 | c.7146T>A p.F2382L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV69322297; called by muse, mutect2, varscan2
- TERT | c.3291G>T p.R1097S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV57245563; called by muse, mutect2, varscan2
- TFAM | c.221-2A>G p.X74_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV65877445; called by muse, mutect2, varscan2
- TIAM1 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV54579797; called by muse, mutect2, varscan2
- TINAG | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV52507391; called by muse, mutect2, varscan2
- TJP1 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV62047533; called by muse, mutect2, varscan2
- TLK1 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV62633775; called by muse, mutect2, varscan2
- TNN | c.2858T>C p.V953A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53438266; called by muse, mutect2, varscan2
- TNR | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV54875537, COSV54919367; called by muse, mutect2, varscan2
- TRIM47 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV54669946; called by muse, mutect2, varscan2
- TRIM6 | c.1411T>C p.Y471H | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763199866, COSV53479791; called by muse, mutect2, varscan2
- TRIP13 | c.956T>A p.I319N | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51322883; called by muse, mutect2, varscan2
- TSGA10IP | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1230515344, COSV73245459; called by muse, mutect2, varscan2
- UPF3B | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs757733776, COSV52232281, COSV99352091; called by muse, mutect2, varscan2
- USH2A | c.13444G>A p.D4482N | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.545); catalogued as COSV56453554; called by muse, mutect2, varscan2
- USH2A | c.8918T>C p.L2973P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as CD153043, COSV56453569; called by muse, mutect2, varscan2
- VWC2L | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV56980739; called by muse, mutect2, varscan2
- WDFY3 | c.7837G>T p.D2613Y | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55697355, COSV99886022; called by muse, mutect2, varscan2
- WDR47 | c.2292G>T p.W764C (on ENST00000369962 / NM_001142551.2; = p.W765C on NM_014969.5) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63060393; called by muse, varscan2
- ZBBX | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56792161; called by muse, mutect2, varscan2
- ZBTB40 | c.2995A>C p.T999P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100988867, COSV65146672; called by muse, mutect2, varscan2
- ZBTB8A | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57144470; called by muse, mutect2, varscan2
- ZBTB8OS | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV59387272; called by muse, mutect2, varscan2
- ZDBF2 | c.1472G>C p.S491T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV65630943; called by muse, mutect2, varscan2
- ZNF112 | c.21G>T p.M7I (on ENST00000337401 / NM_001083335.2; = p.M1? on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61622445; called by muse, mutect2, varscan2
- ZNF157 | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65659049, COSV65659994; called by muse, mutect2, varscan2
- ZNF280C | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63970163; called by muse, mutect2, varscan2
- ZNF616 | c.2057A>T p.K686M | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV57513891; called by muse, mutect2, varscan2
- ZNF654 | c.2535G>T p.Q845H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58807616; called by muse, mutect2, varscan2
- ZNFX1 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.315); catalogued as COSV65580164; called by muse, mutect2, varscan2
- ZNFX1 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.015); catalogued as COSV65580178; called by muse, mutect2, varscan2
- ACSS2 | c.243del p.Y82Tfs*5 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- B4GALT6 | c.57_58insGTC p.I19_F20insV | In Frame Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel
- EIF2AK3 | c.2245_2246delinsTCT p.E749Sfs*5 | Frame Shift Ins (INS) | VAF 62/325 reads (19%) | called by pindel, varscan2*
- HUWE1 | c.7196del p.N2399Tfs*6 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- LCMT2 | c.1968_1990del p.L657Ffs*33 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel
- SLC25A5 | c.660del p.T221Lfs*6 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TPTE | c.1325T>C p.V442A (on ENST00000618007 / NM_199261.4; = p.V424A on NM_199259.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.159); called by muse, mutect2
- TRAV5 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV9-2 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ACD | c.291C>T p.P97= (on ENST00000620338; = p.P11= on NM_022914.3) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV54671033; called by muse, mutect2, varscan2
- ADAMTS16 | c.1959C>T p.A653= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs759807523, COSV56978522, COSV56993777; called by muse, mutect2, varscan2
- ANGPT4 | c.1464C>T p.S488= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV67920733, COSV67921845; called by muse, mutect2, varscan2
- ARFGEF1 | c.1728C>A p.A576= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51618999; called by muse, mutect2, varscan2
- ATP2B3 | c.3639C>A p.L1213= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV54864768; called by muse, mutect2, varscan2
- BAZ2B | c.2925G>A p.A975= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs775080980, COSV54275211, COSV54277257; called by muse, mutect2, varscan2
- BCL11A | c.2286G>A p.G762= (on ENST00000335712 / NM_001365609.1; = p.G796= on NM_022893.4) | Silent (SNP) | VAF 18/217 reads (8%) | catalogued as COSV59639026; called by muse, mutect2
- CDH18 | c.1317C>A p.T439= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV56970694; called by muse, mutect2, varscan2
- CLN8 | c.75C>T p.S25= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1276904511, COSV58671653; ClinVar: likely benign; called by muse, mutect2, varscan2
- COX8C | c.159G>A p.T53= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV56378576; called by muse, mutect2, varscan2
- DDX53 | c.1758G>T p.L586= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV60070372; called by muse, mutect2, varscan2
- FAM47C | c.1755G>A p.E585= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV63731105; called by muse, mutect2, varscan2
- FCRL5 | c.2902C>T p.L968= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV62521480; called by muse, mutect2, varscan2
- GALNS | c.705G>T p.T235= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV51938805, COSV51941250; called by muse, mutect2, varscan2
- HIPK2 | c.1734C>T p.T578= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs775964593, COSV61233840; called by muse, mutect2, varscan2
- IGHV3-66 | c.279C>A p.S93= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- INTS7 | c.774G>A p.Q258= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs766911931, COSV65344155; called by muse, mutect2, varscan2
- LRP6 | c.949C>T p.L317= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV53796280; called by muse, mutect2, varscan2
- LY9 | c.1014C>T p.Y338= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1286820975, COSV54434505, COSV54436443; called by muse, mutect2, varscan2
- MAP2K4 | c.1167A>T p.P389= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV62261568; called by muse, mutect2, varscan2
- MDC1 | c.4095A>G p.S1365= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV64528537; called by muse, mutect2, varscan2
- MDGA1 | c.2856G>A p.A952= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs757335830, COSV51792047; called by muse, mutect2, varscan2
- MED30 | c.45C>G p.P15= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV52068701; called by muse, mutect2, varscan2
- MKRN3 | c.1395T>G p.L465= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1406842327, COSV58812799; called by muse, mutect2, varscan2
- MPL | c.366G>A p.Q122= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV65247797; called by muse, mutect2, varscan2
- MPO | c.2100C>A p.P700= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV51863431; called by muse, mutect2, varscan2
- MPZL1 | c.573T>C p.Y191= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1312649895, COSV63257536; called by muse, mutect2, varscan2
- MUSK | c.1689C>A p.P563= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV51899331; called by muse, varscan2
- NAV3 | c.5304C>A p.P1768= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV57118616; called by muse, mutect2, varscan2
- NCKAP5 | c.4656A>G p.K1552= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV58481112; called by muse, mutect2, varscan2
- NLRP10 | c.846A>T p.T282= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV60783272; called by muse, mutect2, varscan2
- OR10A4 | c.516C>A p.P172= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV65841747; called by muse, mutect2, varscan2
- OR14A16 | c.225G>T p.T75= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs757667932, COSV62926987, COSV62927357; called by muse, mutect2, varscan2
- OR2B2 | c.507T>C p.C169= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV57580967; called by muse, mutect2, varscan2
- OR5D18 | c.342T>C p.F114= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV61739066; called by muse, mutect2, varscan2
- OR5J2 | c.340T>C p.L114= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs746455332, COSV56623817; called by muse, mutect2, varscan2
- PAIP1 | c.648T>C p.Y216= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs745805258, COSV59088234; called by muse, mutect2, varscan2
- PCDH12 | c.2997A>C p.T999= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV51525396; called by muse, mutect2, varscan2
- PLCB4 | c.2877G>A p.T959= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs749780243, COSV53822278; called by muse, mutect2, varscan2
- PLEKHG2 | c.1641G>T p.L547= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52691406; called by muse, mutect2, varscan2
- PXDNL | c.3417C>G p.A1139= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV62498515, COSV62501035; called by muse, mutect2, varscan2
- RBMX | c.462A>T p.P154= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV57811888; called by muse, varscan2
- RIMS2 | c.1587T>C p.D529= (on ENST00000666250 / NM_001348490.2; = p.D337= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV51733389; called by muse, mutect2, varscan2
- RORC | c.999G>A p.E333= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59096386; called by muse, mutect2, varscan2
- SCN2A | c.2604T>C p.N868= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV51858616; called by muse, mutect2, varscan2
- SLC35F3 | c.153G>A p.A51= (on ENST00000366617 / NM_001300845.1; = p.A120= on NM_173508.4) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1165603515, COSV64018057; called by muse, mutect2, varscan2
- SYN1 | c.333C>A p.A111= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55951712; called by muse, mutect2
- SYTL2 | c.2043C>A p.G681= (on ENST00000528231 / NM_001162951.2; = p.G657= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV60364981; called by muse, mutect2, varscan2
- THAP7 | c.144C>T p.P48= | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as COSV53152639; called by muse, mutect2, varscan2
- TMEM38A | c.351C>T p.I117= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV51821552; called by muse, mutect2, varscan2
- TTN | c.94704T>C p.A31568= (on ENST00000591111; = p.A24144= on NM_003319.4) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV60417359; called by muse, mutect2, varscan2
- USP18 | c.501G>T p.L167= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53174813; called by muse, varscan2
- ZFP37 | c.987C>A p.A329= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV65289086; called by muse, mutect2, varscan2
- ZMYM3 | c.1278C>T p.S426= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1569225987, COSV58741389; called by muse, mutect2
- ZSCAN9 | c.472C>T p.L158= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV52849899, COSV52851227; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827374 A>T | 3'Flank (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CLLU1 | n.1977-907T>C | Intron (SNP) | VAF 22/73 reads (30%) | catalogued as COSV65903560; called by muse, mutect2, varscan2
- CR1 | c.487+11964T>C | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65464984; called by muse, varscan2
- HNF4G | c.-7_-6del | 5'UTR (DEL) | VAF 12/49 reads (24%) | called by pindel, varscan2
- KIR3DX1 | n.722A>T | RNA (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55596627, COSV55601924; called by muse, mutect2, varscan2
- MIR506 | n.112C>A | RNA (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
